Gene-level copy-number profile of tumor specimen TCGA-C5-A2M1-01A from TCGA case TCGA-C5-A2M1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 37.9 years (13,835 days).
Specimen TCGA-C5-A2M1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.9537e111-3721-4b10-af03-2b6235155955.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A2M1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3bc2c3e7-9283-4137-a4f2-6dcf73e33182

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 7,454; copy number 2: 50,468; copy number 3: 752; copy number 4: 710; copy number 6: 236; copy number 7: 28; copy number 8: 15; copy number 12: 126; copy number 19: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A2M1-01A-11D-A18H-01): tumor purity 0.71, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:161,347,417–162,727,775, 1 gene (within-gene range 0–2): PRKN.
- chr6:162,568,379–164,348,644, 23 genes: KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P, AL136225.1, Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 408 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,735,434–127,742,951, 1 gene, copy number 19: MYC.
- chr8:127,795,962–127,890,720, 2 genes, copy number 19: MIR1204, AC084123.1.
- chr14:18,333,726–23,751,150, 405 genes, copy number 6–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,454. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
